FM case AD11304 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/268e89a7-4eb1-43ee-978a-e78b6de80726

Female, 31.8 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
